Gene-level copy-number profile of tumor specimen C3L-08992-02 (profiled together with C3L-08992-04) from CPTAC case C3L-08992, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.1 years (25,231 days).
Specimen C3L-08992-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a34fab1-19cb-4683-bffa-b9c049b0713a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08992-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/599c8970-c2dd-4d75-bae9-a1e511bf319e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 6,290; copy number 2: 50,965; copy number 3: 1,107; copy number 4: 30; copy number 5: 2; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:93,784,227–93,850,618, 3 genes (within-gene range 0–2): MED17, VSTM5, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:66,980,120–66,995,587, 2 genes, copy number 5 (within-gene range 2–5): RN7SL43P, SBDS.
- chr16:24,845,841–25,021,023, 3 genes, copy number 6: SLC5A11, ARHGAP17, AC133552.1.

Autosomal genes at a single copy (total copy number 1): 5,170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
